Surgical pathology report (de-identified scan), TCGA case TCGA-19-5954, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5954-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

TCGA - 19 - 5954

A. RIGHT PARIETAL LOBE OF BRAIN, T=-5, BIOPSY:
--BRAIN PARENCHYMA, NO SOLID TUMOR IDENTIFIED.

B. RIGHT PARIETAL LOBE, T=0, C. T+5 AND D. RIGHT PARIETAL BRAIN TUMOR, BIOPSY AND
EXCISION:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Touch imprint and microscopic,
No histopathologically apparent tumor.

B.C. Touch imprint and microscopic,
Glioblastoma multiforme.

Clinical History:

Brain tumor
Right parietal

Specimens Submitted As:

A: T=-5
B: T=0
C: T+5
D: BRAIN TUMOR RIGHT PARIETAL

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "T=-5", is a 0.4 x 0.3 x 0.1 cm pink-white soft tissue aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent in one cassette.

B: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "T=0", is a 1 x 0.5 x 0.3 cm pink-white soft tissue aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent in one cassette.

C: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "T=+5", is a 1 x 0.5 x 0.3 cm pink-white soft tissue aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent in one cassette.

[page 2 of 2]
[REDACTED]

D: Received fresh, labeled with the patient's name and number, and "perm", are multiple irregular, opaque white tan, soft tissue fragments measuring in aggregate 4.0 x 3.4 x 0.7 cm. A portion of specimen is submitted to [REDACTED]. The remaining tissue is submitted entirely in three cassettes.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file b749b1ea-6995-4e93-a843-ef8a76517cee (TCGA-19-5954.938C87ED-DD66-4300-8833-57111EB280BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).